Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17Q, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17Q-01A (Primary Tumor).

[page 1 of 3]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium C54.1

Surgical Pathology

DIAGNOSIS:

A. Uterus, hysterectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 1 to 2 (of 3) is identified forming a mass (2.5 x 1.5 x 1.0 cm) partially involving the polyp and adjacent endometrium located in the upper fundus. The tumor invades 0.3 cm into the myometrium (total myometrial thickness, 2.5 cm). The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. Multiple (3) intramural leiomyomata (ranging in size from 1.0 cm to 1.5 cm in greatest dimension) are identified. [AJCC pT1bN0MX]

B, C. Ovary and fallopian tube, right and left, bilateral salpingo-oophorectomy: Atrophic ovaries and unremarkable fallopian tubes.

D. Lymph nodes, right pelvic, dissection: Multiple (17) right pelvic lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

E. Lymph nodes, left pelvic, biopsy: Multiple (12) left pelvic lymph nodes are negative for tumor.

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

[page 2 of 3]
GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 200.0 gram uterus with attached unremarkable cervix. The uterine serosa is smooth. There is a 3.5 x 2.5 x 2.0 cm polypoid mass in the upper fundus of the endometrial cavity with 2.5 cm myometrial thickness. Grossly, there is 3.0 mm of invasion. There are multiple (3) intramural leiomyomas (ranging in size from 1.0 cm to 1.5 cm in greatest dimension). Representative sections are submitted.

B. Received fresh labeled "right tube & ovary" is a 3.5 x 2.3 x 0.7 cm ovary with an 8.0 x 0.7 cm attached fallopian tube. The ovary has a smooth outer surface and a cystic (0.8 x 0.7 x 0.3 cm) cut surface. There is a 0.5 x 0.5 x 0.5 cm white nodule on the surface. Representative sections submitted.

C. Received fresh labeled "left tube & ovary" is a 3.0 x 3.0 x 1.2 cm ovary with a 7.0 x 0.7 cm attached fallopian tube. The ovary has a smooth outer surface and a cystic (1.5 x 1.4 x 1.1 cm) cut surface. Representative sections submitted.

D. Received fresh labeled "right pelvic nodes" is a 8.9 x 4.9 x 2.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "left pelvic nodes" is an 8.0 x 3.0 x 2.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus

1 Tumor 1

2 Tumor 2

[page 3 of 3]
- 3 Cervix
- 4 Myometrium
- 5 Endometrial mass 1(bottom)
- 6 Endometrial mass 1(top)
- 7 Endometrial mass 2
- 8 Endometrial mass 3
- 9 Endometrial mass 4
- 10 endometrial mass 5

Part B: Right tube and ovary

- 1 Rt ovary
- 2 Rt fallopian tube

Part C: Left tube and ovary

- 1 Lt ovary
- 2 Lt fallopian tube

Part D: Right Pelvic Lymph Nodes

- 1 Rt pelvic LN's 4 (D1)
- 2 Rt pelvic LN's 3 (D2)
- 3 Rt pelvic LN's 1 (D3)
- 4 Rt pelvic LN's 1 (D4)
- 5 Rt pelvic LN's 2 (D5)
- 6 Rt pelvic LN's 1 (D6)
- 7 Rt pelvic LN's 4 (D7)
- 8 Rt pelvic LN's 1 (D8)
- 9 Rt pelvic LN's 1of2 (D9)
- 10 Rt pelvic LN's 2of2 (D9)

Part E: Left Pelvic Nodes

- 1 Lt pelvic lns-1(E1)
- 2 Lt pelvic lns-3(E2)
- 3 Lt pelvic lns-1(E3)
- 4 Lt pelvic lns-1(E4)
- 5 Lt pelvic lns-3(E5)
- 6 Lt pelvic lns-1(E6)
- 7 Lt pelvic lns-2(E7)

Source: NCI Genomic Data Commons file abf534cb-a585-4648-a483-cf6c108fc0d5 (TCGA-D1-A17Q.698079B6-EB07-4491-9672-4BDE4E5DAC49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).